Somatic mutation profile of tumor specimen 0DLZOH from CCDI case PBBZLW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 10.3 years (3,754 days).
Specimen 0DLZOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2cae91a-3e03-4bd2-9eb5-46e21c94b017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZNC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d900829-c9c7-48fd-9bfc-506015c674ab

The open-access MAF lists 57 somatic variants for this specimen: 29 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 16, Intron 5, 3'UTR 4, Nonsense Mutation 2, Splice Site 1, 5'UTR 1, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 155/575 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALB | c.270+1del p.X90_splice | Splice Site (DEL) | VAF 158/551 reads (29%) | catalogued as CS1511747, COSV55742721; called by mutect2, varscan2
- APP | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 250/789 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV61002990; called by mutect2, varscan2
- C8orf82 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 92/628 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245889829; called by muse, mutect2, varscan2
- CHTF18 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 183/718 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs749093068, COSV99136042; called by muse, mutect2, varscan2
- CPSF1 | c.2288G>A p.R763Q | Missense Mutation (SNP) | VAF 91/714 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs763605694; called by muse, mutect2, varscan2
- CSMD3 | c.11005G>T p.E3669* (on ENST00000297405 / NM_001363185.1; = p.E3500* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 212/1682 reads (13%) | catalogued as COSV52193289; called by muse, mutect2, varscan2
- DDX42 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 218/986 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as rs370205856; called by muse, mutect2, varscan2
- GRID1 | c.2284G>A p.G762S | Missense Mutation (SNP) | VAF 203/759 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.524); catalogued as rs769403835, COSV60037244; called by muse, mutect2, varscan2
- KIF4B | c.2684G>C p.C895S | Missense Mutation (SNP) | VAF 265/935 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs762787846; called by muse, mutect2, varscan2
- LRRK2 | c.6422C>G p.T2141R | Missense Mutation (SNP) | VAF 195/1336 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as CM081687, COSV54149375; called by muse, mutect2, varscan2
- NEURL1 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 132/474 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs200676641, COSV63509472; called by muse, varscan2
- NXF1 | c.779T>C p.I260T | Missense Mutation (SNP) | VAF 264/909 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1487339757; called by muse, mutect2, varscan2
- PSMA7 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 232/1070 reads (22%) | catalogued as COSV100065005, COSV59211905; called by muse, mutect2, varscan2
- PTPRS | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 136/607 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748364975, COSV53619703; called by muse, mutect2, varscan2
- RNF213 | c.11716G>A p.G3906R | Missense Mutation (SNP) | VAF 200/1176 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs1025831748, COSV60389125; called by muse, mutect2, varscan2
- SPPL2B | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 90/449 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.096); catalogued as rs372598649; called by muse, mutect2, varscan2
- ADGRV1 | c.6909G>T p.L2303F | Missense Mutation (SNP) | VAF 278/1263 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP55 | c.576del p.V193Sfs*3 | Frame Shift Del (DEL) | VAF 188/944 reads (20%) | called by mutect2, varscan2
- CWC22 | c.2221G>C p.D741H | Missense Mutation (SNP) | VAF 340/1580 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- DNAJC14 | c.1270C>G p.P424A | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- EFHD2 | c.472C>G p.R158G | Missense Mutation (SNP) | VAF 254/809 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- HK3 | c.2744G>T p.C915F | Missense Mutation (SNP) | VAF 177/551 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LHPP | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 115/454 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR11H7 | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 102/486 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- PCK2 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 165/719 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RIMBP2 | c.5G>C p.R2P | Missense Mutation (SNP) | VAF 162/702 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SMCHD1 | c.4612A>T p.I1538L | Missense Mutation (SNP) | VAF 204/656 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UBR5 | c.5538G>A p.M1846I | Missense Mutation (SNP) | VAF 221/1428 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- ABCC2 | c.759C>T p.A253= | Silent (SNP) | VAF 243/987 reads (25%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13305C>T p.A4435= | Silent (SNP) | VAF 150/626 reads (24%) | called by muse, mutect2, varscan2
- ASXL2 | c.423G>A p.Q141= | Silent (SNP) | VAF 166/735 reads (23%) | catalogued as COSV55463515; called by muse, mutect2, varscan2
- DNAH17 | c.10086C>T p.F3362= | Silent (SNP) | VAF 178/983 reads (18%) | catalogued as rs760960985, COSV67756217; called by muse, mutect2, varscan2
- EFR3B | c.216C>T p.Y72= | Silent (SNP) | VAF 174/792 reads (22%) | catalogued as rs754323247; called by muse, mutect2, varscan2
- GIPC3 | c.651C>T p.S217= | Silent (SNP) | VAF 132/640 reads (21%) | catalogued as rs779708218; called by muse, mutect2, varscan2
- KLHL40 | c.1245C>T p.Y415= | Silent (SNP) | VAF 206/695 reads (30%) | catalogued as rs781322851, COSV55134199; called by muse, mutect2, varscan2
- MAGI3 | c.1398C>G p.L466= | Silent (SNP) | VAF 244/820 reads (30%) | called by muse, mutect2, varscan2
- MUC5B | c.12261G>A p.P4087= | Silent (SNP) | VAF 224/805 reads (28%) | catalogued as rs751851132; called by muse, mutect2, varscan2
- OR2T6 | c.450C>T p.F150= | Silent (SNP) | VAF 26/906 reads (3%) | catalogued as rs750148782, COSV63215990, COSV63216034; called by muse, mutect2
- RTTN | c.4194G>A p.T1398= | Silent (SNP) | VAF 275/887 reads (31%) | catalogued as rs776259891, COSV55346453, COSV99731550; called by muse, mutect2, varscan2
- SLC35G3 | c.387C>T p.N129= | Silent (SNP) | VAF 249/802 reads (31%) | catalogued as rs532177633, COSV52011759; called by muse, mutect2, varscan2
- TCTN1 | c.1509C>T p.L503= (on ENST00000551590 / NM_001173975.3; = p.L489= on NM_024549.6) | Silent (SNP) | VAF 189/875 reads (22%) | called by muse, mutect2, varscan2
- TERB2 | c.273G>T p.A91= | Silent (SNP) | VAF 150/333 reads (45%) | catalogued as COSV61651087; called by muse, mutect2, varscan2
- VPS54 | c.78G>A p.P26= | Silent (SNP) | VAF 282/1140 reads (25%) | catalogued as rs751756431; called by muse, varscan2
- YBX3 | c.609C>T p.S203= | Silent (SNP) | VAF 181/1328 reads (14%) | called by muse, mutect2, varscan2
- ADCK5 | c.343-33G>A | Intron (SNP) | VAF 78/668 reads (12%) | called by muse, mutect2, varscan2
- CD36 | c.818+55T>C | Intron (SNP) | VAF 143/547 reads (26%) | called by muse, mutect2, varscan2
- CROCC2 | c.2835+18C>T | Intron (SNP) | VAF 78/296 reads (26%) | catalogued as rs549011961; called by muse, mutect2, varscan2
- GRM3 | c.-54C>A | 5'UTR (SNP) | VAF 143/563 reads (25%) | catalogued as rs930240078; called by muse, mutect2, varscan2
- IL1A | c.*74C>G | 3'UTR (SNP) | VAF 49/198 reads (25%) | called by muse, mutect2, varscan2
- LZTFL1 | c.*40A>G | 3'UTR (SNP) | VAF 220/771 reads (29%) | called by muse, mutect2, varscan2
- MUC19 | n.6280A>G | RNA (SNP) | VAF 178/958 reads (19%) | called by muse, mutect2, varscan2
- NPY5R | c.-9-36T>C | Intron (SNP) | VAF 169/449 reads (38%) | called by muse, mutect2, varscan2
- SYNGR2 | c.*13G>A | 3'UTR (SNP) | VAF 121/712 reads (17%) | catalogued as rs372282851, COSV104387700; called by muse, mutect2, varscan2
- TUBB4A | chr19:6502690 G>C | 5'Flank (SNP) | VAF 110/505 reads (22%) | called by muse, mutect2, varscan2
- VIPR1 | c.*90G>A | 3'UTR (SNP) | VAF 29/111 reads (26%) | catalogued as rs1026208560; called by muse, mutect2, varscan2
- ZFAND4 | c.2048+46C>G | Intron (SNP) | VAF 118/439 reads (27%) | catalogued as rs373577871; called by muse, mutect2, varscan2
